Somatic mutation profile of tumor specimen TARGET-20-PATEID-09A (aliquot TARGET-20-PATEID-09A-01D) from TARGET case TARGET-20-PATEID, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (969 days).
Specimen TARGET-20-PATEID-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aeb52521-57df-42c6-8161-fdec7af18fe3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATEID-14A (Bone Marrow Normal), aliquot TARGET-20-PATEID-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b2e88a9-5a70-4024-9f06-e9d4f055751a

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15536G>A p.R5179H | Missense Mutation (SNP) | VAF 94/219 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs267607237, CM105472, COSV56428259, COSV56447076, COSV56496109; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 43/198 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 39/204 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2001C>A p.F667L (on ENST00000460911 / NM_001203247.2; = p.F672L on NM_004456.5) | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57453519, COSV57455265; called by muse, mutect2, varscan2
